Somatic mutation profile of tumor specimen 0DUSSU from CCDI case PBCLTP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.7 years (5,021 days).
Specimen 0DUSSU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80ad863a-20df-4278-baf9-0bc6cd690cb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUSSD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d3d1cbe-8418-497a-9476-2d2303cfcc62

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC2 | c.5227C>T p.R1743W | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs45517412, CM052391, CM091157, COSV51918349; ClinVar: not provided / pathogenic; called by muse, varscan2
- TAF1L | c.4124G>A p.R1375Q | Missense Mutation (SNP) | VAF 113/541 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs746394860; called by muse, mutect2, varscan2
- STAP2 | c.698dup p.V234Rfs*28 | Frame Shift Ins (INS) | VAF 24/209 reads (11%) | called by mutect2, varscan2
